CCDI case PBCRKT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/34e61454-6735-4735-b264-53e707ba1b04

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Brain stem; Age at diagnosis: 8.2 years (2,989 days).

Biospecimens (3 samples)
- Sample 0DXJEK: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DXJF4: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DXJH3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
